CCDI case PBCHIB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/f80e0292-5662-4b86-b16f-23343270a2a4

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 16.7 years (6,102 days).

Biospecimens (3 samples)
- Sample 0DS0ZD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DS0ZL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS0ZY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
